Gene-level copy-number profile of tumor specimen ALCH-B3B0-TTP1-A from ALCHEMIST case ALCH-B3B0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.1 years (28,163 days).
Specimen ALCH-B3B0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1e5f5097-7179-45d5-86ff-e19a59600420.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3B0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/57ef1e9b-f172-413d-85c5-734f7e4b379a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 114; copy number 1: 4,362; copy number 2: 52,346; copy number 3: 1,435; copy number 4: 96; copy number 5: 22; copy number 6: 2; copy number 7: 10.

Homozygous deletions (total copy number 0; autosomes only): 111 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:944,203–959,309, 1 gene (within-gene range 0–2): NOC2L.
- chr1:966,482–975,865, 1 gene (within-gene range 0–2): PLEKHN1.
- chr1:39,678,648–39,691,485, 1 gene: HPCAL4.
- chr1:175,877,343–175,880,468, 1 gene: LINC01657.
- chr2:130,139,287–130,190,729, 3 genes (within-gene range 0–2): CCDC74B, SMPD4, MZT2B.
- chr2:174,395,730–174,429,575, 1 gene: SCRN3.
- chr3:48,663,776–48,686,364, 3 genes: LINC02585, AC141002.1, NCKIPSD.
- chr3:49,873,347–49,903,873, 3 genes (within-gene range 0–2): ACTBP13, MST1R, AC105935.2.
- chr3:129,543,214–129,551,467, 1 gene: H1-8.
- chr3:194,637,505–194,637,664, 1 gene (within-gene range 0–2): AC046143.2.
- chr4:661,209–674,330, 2 genes (within-gene range 0–3): AC107464.2, ATP5ME.
- chr4:2,059,327–2,069,089, 1 gene: NAT8L.
- chr6:35,794,982–35,797,344, 1 gene: CLPS.
- chr7:45,816,216–45,843,740, 4 genes: CICP20, AC096582.1, AC096582.2, RNU6-326P.
- chr7:74,773,962–74,789,376, 1 gene: NCF1.
- chr7:76,397,518–76,541,459, 9 genes (within-gene range 0–2): ZP3, DTX2, FDPSP2, AC005522.1, UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16.
- chr7:108,994,031–108,995,029, 1 gene: BUB3P1.
- chr7:128,850,162–128,950,038, 6 genes (within-gene range 0–2): FLNC-AS1, KCP, ATP6V1F, ATP6V1FNB, AC025594.1, IRF5.
- chr7:129,209,775–129,213,545, 1 gene (within-gene range 0–3): AC011005.4.
- chr8:27,886,039–27,910,310, 4 genes (within-gene range 0–2): MIR4287, AC069113.1, AC069113.3, AC069113.2.
- chr8:33,436,268–33,436,700, 1 gene (within-gene range 0–2): AC091144.2.
- chr10:87,027,184–87,041,341, 2 genes: AL136982.5, RNU6-529P.
- chr10:102,461,881–102,502,712, 2 genes (within-gene range 0–1): ACTR1A, AL121928.1.
- chr11:76,186,325–76,210,736, 2 genes: WNT11, AP000785.1.
- chr14:102,036,315–102,066,228, 1 gene (within-gene range 0–2): AL118558.1.
- chr14:102,539,644–102,555,826, 2 genes: MIR4309, LINC02323.
- chr14:103,912,288–103,928,269, 1 gene: ATP5MPL.
- chr15:25,180,497–25,225,284, 25 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr16:1,943,974–1,968,975, 9 genes: RPL3L, NDUFB10, RPS2, SNORA10, SNORA64, AC005363.1, SNHG9, SNORA78, RNF151.
- chr17:81,843,165–81,843,958, 1 gene (within-gene range 0–2): AC145207.3.
- chr19:12,646,511–12,696,631, 11 genes (within-gene range 0–2): MAN2B1, AC010422.5, WDR83, AC010422.8, WDR83OS, AC010422.7, DHPS, AC010422.2, GNG14, FBXW9, AC018761.4.
- chr19:41,860,255–41,872,925, 2 genes: RPS19, MIR6797.
- chr19:56,127,236–56,185,775, 4 genes: AC024580.2, ZNF444, AC024580.1, GALP.
- chr20:3,208,868–3,223,870, 1 gene: ITPA.
- chr22:43,038,585–43,052,366, 1 gene (within-gene range 0–2): TTLL1-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 34 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,292,390–1,309,609, 1 gene, copy number 5 (within-gene range 4–5): ACAP3.
- chr1:1,308,597–1,349,418, 8 genes, copy number 5: PUSL1, INTS11, MIR6727, AL139287.1, CPTP, TAS1R3, DVL1, MIR6808.
- chr1:231,363,751–231,528,603, 2 genes, copy number 5 (within-gene range 2–5): EGLN1, AL445524.2.
- chr9:83,707,594–83,713,378, 1 gene, copy number 5 (within-gene range 2–5): AL354920.1.
- chr9:136,738,167–136,766,255, 5 genes, copy number 7 (within-gene range 2–7): AL355987.1, LCN6, MIR6722, LCN8, LCN15.
- chr14:18,418,775–18,419,273, 1 gene, copy number 5: BNIP3P6.
- chr14:64,449,106–64,540,368, 4 genes, copy number 5 (within-gene range 2–5): ZBTB25, AKAP5, ZBTB1, AL049869.2.
- chr15:78,898,840–78,906,809, 2 genes, copy number 5: RNU6-415P, AC011944.2.
- chr17:83,220,527–83,240,804, 2 genes, copy number 6: AC139099.1, RPL23AP87.
- chr20:64,290,187–64,327,972, 3 genes, copy number 5: CICP4, LINC00266-1, AL137028.1.
- chr21:44,217,014–44,262,216, 5 genes, copy number 7: ICOSLG, AP001059.2, AP001059.1, DNMT3L, DNMT3L-AS1.

Autosomal genes at a single copy (total copy number 1): 3,209. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
